MMRF case MMRF_2642 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7e7e4059-d620-4c8f-93e5-617b971290dc

Demographics
Sex at birth: female; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.3 years (21,664 days); ISS stage: II; Days to last known disease status: 567 days (1.6 years); Days to last follow up: 567 days (1.6 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -15, day 567.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 377 ×10⁹/L.
- Hemoglobin 7.81 mmol/L.
- Albumin 34 g/L.
- Creatinine 67.2 µmol/L.
- Calcium 2.62 mmol/L.
- M Protein 0.82 g/dL.
- Absolute Neutrophil 5.08 ×10⁹/L.
- Beta 2 Microglobulin 3.6 µg/mL.

Other clinical attributes
- Day -15: Weight: 48 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_2642_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -15 days.
- Sample MMRF_2642_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -15 days.
